Somatic mutation profile of tumor specimen TCGA-KU-A66S-01A (aliquot TCGA-KU-A66S-01A-21D-A30E-08) from TCGA case TCGA-KU-A66S, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 69.7 years (25,454 days).
Specimen TCGA-KU-A66S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efae1084-7861-4104-9a5b-fc7db25aaf53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KU-A66S-10A (Blood Derived Normal), aliquot TCGA-KU-A66S-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14e0ca12-4c76-4260-8819-f53cb8df46a7

The open-access MAF lists 533 somatic variants for this specimen: 415 protein-altering or splice-affecting, 106 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 368, Silent 106, Nonsense Mutation 16, Frame Shift Del 11, Splice Site 8, Frame Shift Ins 6, Splice Region 4, Intron 4, 5'Flank 3, RNA 2, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.4381C>T p.R1461* | Nonsense Mutation (SNP) | VAF 33/50 reads (66%) | hotspot (GDC flag); catalogued as COSV61376088; called by muse, mutect2, varscan2
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- NAA15 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as rs1274633498, COSV56719543; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs748398755, COSV50958076; called by muse, mutect2, varscan2
- ABCC8 | c.4467C>G p.F1489L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100217545; called by muse, mutect2, varscan2
- AC100868.1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.596); catalogued as COSV99225064; called by muse, mutect2, varscan2
- ACSS3 | c.1118C>A p.P373Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99699209; called by muse, mutect2, varscan2
- ACTA1 | c.821C>G p.A274G | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.049); catalogued as CM034512, COSV64202997; called by muse, mutect2, varscan2
- ACTR6 | c.1124T>C p.M375T | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.039); catalogued as rs1173404121, COSV99498700; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2805C>G p.H935Q | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as COSV101001999; called by muse, mutect2, varscan2
- ADCY8 | c.3484G>T p.E1162* | Nonsense Mutation (SNP) | VAF 8/128 reads (6%) | catalogued as COSV99653311; called by muse, mutect2
- AHNAK2 | c.5039C>G p.S1680W | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373360672, COSV100318317; called by muse, mutect2
- AKAP12 | c.3589G>A p.E1197K | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV99483931; called by muse, mutect2, varscan2
- AKAP13 | c.2574C>G p.H858Q | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100773826, COSV100774202; called by muse, mutect2, varscan2
- AKIP1 | c.172dup p.H58Pfs*26 | Frame Shift Ins (INS) | VAF 5/19 reads (26%) | catalogued as rs933044487; called by mutect2, pindel, varscan2
- AKNA | c.596G>C p.R199T | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV99800734; called by muse, mutect2, varscan2
- ALDH1A1 | c.1367G>C p.C456S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV99921523; called by muse, mutect2
- ALDH1L1 | c.1994G>A p.S665N | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV99857223; called by muse, mutect2, varscan2
- ALKBH3 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.231); catalogued as COSV100236458; called by muse, mutect2
- ALMS1 | c.4359G>T p.L1453F | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as COSV100043146; called by muse, mutect2, varscan2
- ALOX15B | c.2028C>G p.I676M | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV66480124; called by muse, mutect2
- ANGPT2 | c.112C>A p.H38N | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV100291066; called by muse, mutect2, varscan2
- ANGPT4 | c.1353G>C p.G451= | Splice Region (SNP) | VAF 8/32 reads (25%) | catalogued as COSV101124822; called by muse, mutect2, varscan2
- ANK2 | c.9914C>G p.P3305R | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV100002965; called by muse, mutect2, varscan2
- APOB | c.3958G>C p.A1320P | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.121); catalogued as COSV51957618, COSV99266758; called by muse, mutect2
- AREL1 | c.935G>A p.W312* | Nonsense Mutation (SNP) | VAF 75/209 reads (36%) | catalogued as COSV100707630; called by muse, mutect2, varscan2
- ARHGAP12 | c.666C>G p.S222R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100260732; called by muse, mutect2, varscan2
- ARHGEF19 | c.1376G>T p.C459F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV99580627; called by muse, mutect2, varscan2
- ARMCX2 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV57530454; called by muse, mutect2, varscan2
- ARRDC2 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs200200467; called by muse, mutect2, varscan2
- ASTN2 | c.1897G>A p.A633T (on ENST00000313400 / NM_001365069.1; = p.A582T on NM_014010.5) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs1023495027, COSV100529054; called by muse, mutect2, varscan2
- ATCAY | c.440G>T p.S147I | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.148); catalogued as COSV100008899; called by muse, mutect2, varscan2
- ATIC | c.1399C>G p.L467V | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV99378012; called by muse, mutect2, varscan2
- ATMIN | c.1015G>C p.G339R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as COSV100214709; called by muse, mutect2
- ATP6V0A1 | c.482G>C p.G161A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.422); catalogued as COSV99231340; called by muse, mutect2, varscan2
- ATP8B2 | c.706C>T p.P236S (on ENST00000672630; = p.P203S on NM_001005855.2) | Missense Mutation (SNP) | VAF 143/361 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.557); catalogued as COSV100528130; called by muse, mutect2, varscan2
- ATP9A | c.2232G>C p.E744D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.614); catalogued as COSV100125321; called by muse, mutect2, varscan2
- BBS4 | c.1439C>G p.T480R | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV51436976, COSV99166501; called by muse, mutect2
- BCORL1 | c.3661C>G p.L1221V | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99500235; called by muse, mutect2
- BCR | c.1670A>G p.H557R | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100006764; called by muse, mutect2, varscan2
- BMX | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100564569; called by muse, mutect2, varscan2
- BRMS1 | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV100240337, COSV60819648; called by muse, mutect2, varscan2
- BRWD1 | c.2170C>G p.P724A | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100313752; called by muse, mutect2, varscan2
- BSX | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as COSV100545277; called by muse, mutect2, varscan2
- BTBD7 | c.1575C>G p.I525M | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs1566838361, COSV100598028; called by muse, mutect2, varscan2
- BTK | c.1726A>T p.S576C | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100437750; called by muse, mutect2, varscan2
- CACHD1 | c.1968G>C p.M656I | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.48); catalogued as COSV99262832; called by muse, mutect2, varscan2
- CACNA1E | c.1472C>G p.A491G | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV100704169; called by muse, mutect2
- CACNA1F | c.1185G>T p.Q395H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100545138; called by muse, mutect2
- CACNG4 | c.802G>C p.A268P | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV100047755; called by muse, mutect2, varscan2
- CAPRIN2 | c.906G>C p.K302N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1029353011, COSV99195566; called by muse, mutect2, varscan2
- CARD11 | c.93C>G p.H31Q | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100712255; called by muse, mutect2, varscan2
- CARS1 | c.2006C>G p.A669G | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV99543166; called by muse, mutect2
- CBY2 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100137730, COSV60117749; called by muse, mutect2, varscan2
- CCDC120 | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.066); catalogued as COSV100896751; called by muse, mutect2, varscan2
- CCDC91 | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as COSV60344959; called by muse, mutect2, varscan2
- CCDC91 | c.1304C>A p.T435K | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.286); catalogued as COSV100082173; called by muse, mutect2, varscan2
- CDC42BPB | c.4366C>G p.R1456G | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100775534, COSV63474864; called by muse, mutect2, varscan2
- CDC42EP1 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV99312584; called by muse, mutect2, varscan2
- CDH9 | c.1993G>A p.G665R | Missense Mutation (SNP) | VAF 14/305 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50251232, COSV50257769, COSV99039254; called by muse, mutect2
- CDHR5 | c.1631C>G p.P544R (on ENST00000358353 / NM_001171968.2; = p.P550R on NM_021924.5) | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); catalogued as COSV100363692; called by muse, mutect2
- CELSR3 | c.7590+1G>C p.X2530_splice | Splice Site (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99374308; called by muse, mutect2, varscan2
- CENPE | c.3533A>T p.E1178V | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV99478571; called by muse, mutect2, varscan2
- CFP | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs779108735, COSV99901597; called by muse, mutect2, varscan2
- CHD6 | c.1886C>G p.P629R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100498518; called by muse, mutect2, varscan2
- CHD8 | c.1445G>C p.R482P (on ENST00000646647 / NM_001170629.2; = p.R203P on NM_020920.4) | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101303169; called by muse, mutect2
- CLCN6 | c.2199G>C p.E733D | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.121); catalogued as COSV100412071; called by muse, mutect2
- CLEC2D | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.678); catalogued as COSV99325110; called by muse, mutect2, varscan2
- CLPB | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV99578413; called by muse, mutect2, varscan2
- CLVS1 | c.640C>G p.P214A | Missense Mutation (SNP) | VAF 13/383 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100370338; called by muse, mutect2
- CNTNAP1 | c.466C>G p.R156G | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV52850864, COSV99226755; called by muse, mutect2
- COL24A1 | c.2812C>G p.Q938E | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0.084); catalogued as COSV100993694; called by muse, mutect2, varscan2
- COL24A1 | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); catalogued as COSV100993696; called by muse, mutect2, varscan2
- COL28A1 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as COSV101258805; called by muse, mutect2, varscan2
- COL4A3 | c.3754G>A p.A1252T | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100516729, COSV100516814; called by muse, mutect2, varscan2
- COL9A3 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100673506; called by muse, mutect2, varscan2
- CPA2 | c.674G>C p.G225A | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99744160; called by muse, mutect2
- CPEB1 | c.280C>T p.R94* (on ENST00000617958; = p.R34* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/79 reads (48%) | catalogued as COSV71604286; called by muse, mutect2, varscan2
- CRAT | c.1608C>G p.D536E | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV100540065; called by muse, mutect2
- CREB3L3 | c.1175G>T p.R392L | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99314337; called by muse, mutect2, varscan2
- CREG2 | c.649C>G p.Q217E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100240577; called by muse, mutect2, varscan2
- CRTAC1 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1479216971, COSV100085871, COSV53996376; called by muse, mutect2
- CRYBG1 | c.4528G>C p.A1510P | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as COSV100954576; called by muse, mutect2, varscan2
- CSMD3 | c.9829G>T p.G3277C (on ENST00000297405 / NM_001363185.1; = p.G3108C on NM_052900.3) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52176991, COSV99841236; called by muse, mutect2
- CSMD3 | c.9380G>A p.R3127Q (on ENST00000297405 / NM_001363185.1; = p.R2958Q on NM_052900.3) | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.888); catalogued as rs752773200, COSV52165293, COSV52249136; called by muse, mutect2, varscan2
- CXorf58 | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV101003042; called by muse, mutect2, varscan2
- CYP1B1 | c.260T>G p.I87S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99572782; called by muse, varscan2
- CYP2R1 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV100584958; called by muse, mutect2, varscan2
- DDRGK1 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776117912, COSV100621489; called by muse, mutect2, varscan2
- DHRS4L2 | c.401G>C p.W134S | Missense Mutation (SNP) | VAF 36/459 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100632571; called by muse, mutect2
- DLEC1 | c.1919+2T>A p.X640_splice | Splice Site (SNP) | VAF 40/98 reads (41%) | catalogued as COSV100342985; called by muse, varscan2
- DNAH1 | c.12309G>C p.W4103C | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99964291, COSV99964652; called by muse, mutect2
- DNAH5 | c.4855A>T p.T1619S | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99451995; called by muse, mutect2, varscan2
- DNAH9 | c.9392A>T p.K3131M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99306935; called by muse, mutect2, varscan2
- DNHD1 | c.11898C>G p.S3966R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99600599; called by muse, mutect2, varscan2
- DNHD1 | c.13283C>G p.S4428C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV99600600; called by muse, mutect2, varscan2
- DOP1A | c.3417G>C p.M1139I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99382459; called by muse, mutect2, varscan2
- DSP | c.5604G>C p.K1868N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV101131526; called by muse, mutect2
- DTX1 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771660342, COSV55658850; called by muse, mutect2, varscan2
- DUOX1 | c.3297C>G p.Y1099* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV100368239; called by muse, mutect2, varscan2
- DYNAP | c.587C>G p.T196S (on ENST00000321600; = p.T170S on NM_173629.3) | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as rs747217638, COSV100391789; called by muse, mutect2
- EARS2 | c.1404A>T p.E468D | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV101492184; called by muse, mutect2, varscan2
- EGF | c.3617C>G p.T1206S | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.06); catalogued as COSV99491193; called by muse, mutect2, varscan2
- ELP2 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); catalogued as rs1426683780, COSV60849236; called by muse, mutect2, varscan2
- EMILIN2 | c.215A>T p.Y72F | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as COSV54426160, COSV99598730; called by muse, mutect2, varscan2
- EPB41L3 | c.1957G>T p.A653S | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.933); catalogued as rs201249884, COSV100549782; called by muse, mutect2, varscan2
- ERLIN2 | c.819G>T p.K273N | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV99379720; called by muse, mutect2, varscan2
- ERRFI1 | c.1048C>G p.Q350E | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101088186; called by muse, mutect2, varscan2
- ESR1 | c.559G>T p.V187L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99240178; called by muse, mutect2, varscan2
- EXOC2 | c.196C>G p.Q66E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as COSV100033945; called by muse, mutect2, varscan2
- EXOC4 | c.1721G>T p.R574L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV54091555, COSV99554821; called by muse, mutect2
- F2R | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT tolerated (0.98); PolyPhen benign (0.01); catalogued as COSV100058562; called by muse, mutect2, varscan2
- FAM20A | c.420C>G p.Y140* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99873409; called by muse, mutect2, varscan2
- FAM47A | c.538G>T p.G180C | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.274); catalogued as COSV60494039; called by muse, mutect2, varscan2
- FAM71B | c.1762G>A p.G588S | Missense Mutation (SNP) | VAF 110/272 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as COSV100262215; called by muse, mutect2, varscan2
- FAT4 | c.9007A>C p.K3003Q | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100629376; called by muse, mutect2, varscan2
- FBXO34 | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs368994907; called by muse, mutect2, varscan2
- FBXO9 | c.1201A>G p.I401V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99762568; called by muse, mutect2, varscan2
- FCRL6 | c.509C>A p.A170D | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as COSV100220259, COSV100220295; called by muse, mutect2, varscan2
- FH | c.215C>G p.T72S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100845049; called by muse, mutect2, varscan2
- FILIP1 | c.2549C>T p.S850F | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV99385517; called by muse, mutect2, varscan2
- FLG | c.4418C>G p.A1473G | Missense Mutation (SNP) | VAF 140/428 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100911856; called by muse, mutect2
- FRY | c.6877C>T p.R2293W | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373719773; called by muse, mutect2, varscan2
- FSTL5 | c.448A>C p.N150H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100058554; called by muse, mutect2, varscan2
- FUS | c.1430G>C p.G477A | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.097); catalogued as COSV99568865; called by muse, mutect2, varscan2
- GABRD | c.904C>G p.P302A | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101059561; called by muse, mutect2, varscan2
- GABRQ | c.1456G>T p.V486F | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV64782181; called by muse, mutect2
- GAS6 | c.1365C>G p.D455E | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV100581931; called by muse, mutect2, varscan2
- GAS7 | c.643G>T p.G215C (on ENST00000432992 / NM_201433.2; = p.G75C on NM_003644.3) | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs759708568, COSV100096325, COSV60430902; called by muse, mutect2, varscan2
- GEM | c.783C>G p.S261R | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52596662, COSV99891491; called by muse, mutect2
- GET3 | c.28dup p.V10Gfs*2 | Frame Shift Ins (INS) | VAF 8/21 reads (38%) | catalogued as rs752987623; called by mutect2, pindel, varscan2
- GLMN | c.991G>C p.V331L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.047); catalogued as rs761602030, COSV100950121; called by muse, mutect2, varscan2
- GPR153 | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as rs777963528, COSV100928577, COSV64938699; called by muse, mutect2, varscan2
- GRK7 | c.466G>C p.A156P | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.305); catalogued as COSV53823520, COSV99380066; called by muse, mutect2
- GRM7 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs779305909, COSV100737496; called by muse, mutect2, varscan2
- GRN | c.727C>G p.H243D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99274984; called by muse, mutect2
- HCAR2 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100186578; called by muse, mutect2, varscan2
- HERC5 | c.1711C>G p.L571V | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV99987979; called by muse, mutect2, varscan2
- HMGN5 | c.48A>G p.P16= | Splice Region (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100814977; called by muse, mutect2, varscan2
- HOXB13 | c.389A>C p.Y130S | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99285284; called by muse, mutect2, varscan2
- HP1BP3 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100391973; called by muse, mutect2, varscan2
- HPSE | c.178A>T p.T60S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV100264443; called by muse, mutect2, varscan2
- HSD17B10 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99395043; called by muse, mutect2, varscan2
- HSD17B4 | c.1249G>C p.A417P (on ENST00000414835 / NM_001199291.3; = p.A392P on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99820005; called by muse, mutect2
- HSDL1 | c.556C>G p.H186D | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99550434; called by muse, mutect2
- IARS2 | c.1152G>T p.M384I | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as COSV100228481; called by muse, mutect2, varscan2
- ICAM3 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99349182; called by muse, mutect2, varscan2
- IGSF1 | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1349561128, COSV100812199; called by muse, mutect2, varscan2
- IGSF9 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.521); catalogued as COSV100829648, COSV63641853; called by muse, mutect2, varscan2
- IL17RA | c.1516G>C p.E506Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV100083195, COSV100083332, COSV60051745; called by muse, mutect2, varscan2
- IL4R | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.741); catalogued as rs753586692, COSV50149735; called by muse, mutect2, varscan2
- IMPDH2 | c.1502G>C p.G501A | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100455118; called by muse, mutect2, varscan2
- INHBA | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99638046; called by muse, mutect2, varscan2
- IPO13 | c.1781T>C p.L594P | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV100961283; called by muse, mutect2, varscan2
- JAG1 | c.1298G>C p.S433T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV54758044; called by muse, mutect2, varscan2
- JPH4 | c.1594C>T p.L532F | Missense Mutation (SNP) | VAF 150/353 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.793); catalogued as COSV100436876, COSV58116838; called by muse, mutect2, varscan2
- KCNA1 | c.115G>C p.V39L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.535); catalogued as COSV101230310, COSV66837856; called by muse, mutect2, varscan2
- KCNJ3 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99716183; called by muse, mutect2
- KCNV1 | c.931G>C p.V311L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV99819263, COSV99819543; called by muse, mutect2, varscan2
- KDM5B | c.1377G>T p.W459C | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99351031; called by muse, mutect2
- KEAP1 | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320679251, COSV50284380, COSV99408044; called by muse, mutect2, varscan2
- KEAP1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV50260660; called by muse, mutect2, varscan2
- KIAA0319 | c.899C>G p.T300R | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs751748358, COSV100985701; called by muse, mutect2, varscan2
- KIAA1109 | c.11209G>C p.D3737H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV99167845; called by muse, mutect2, varscan2
- KIAA1210 | c.3472G>C p.A1158P | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs181240628, COSV101274314; called by muse, mutect2, varscan2
- KIF21B | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100144819, COSV59759564; called by muse, mutect2, varscan2
- KIF4B | c.1229C>A p.A410D | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV101469359; called by muse, mutect2, varscan2
- KIFC3 | c.1218+1G>C p.X406_splice | Splice Site (SNP) | VAF 21/79 reads (27%) | catalogued as COSV101109056, COSV101109275; called by muse, mutect2, varscan2
- KIRREL3 | c.1189G>T p.V397L | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV101375211; called by muse, mutect2, varscan2
- KLHL4 | c.2037C>A p.D679E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100910024; called by muse, mutect2, varscan2
- KLHL40 | c.898C>G p.R300G | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs745626348, COSV99825663; called by muse, mutect2, varscan2
- KMT2C | c.10186C>G p.Q3396E | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100074467; called by muse, mutect2, varscan2
- KRT74 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs1256665724, COSV99977602; called by muse, mutect2, varscan2
- KRTAP26-1 | c.109G>T p.G37* | Nonsense Mutation (SNP) | VAF 49/126 reads (39%) | catalogued as COSV100860449, COSV62129034; called by muse, mutect2, varscan2
- L1CAM | c.1371T>A p.S457R | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV100649356; called by muse, mutect2, varscan2
- LATS1 | c.681C>G p.H227Q | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.36); catalogued as COSV99486392; called by muse, mutect2, varscan2
- LCT | c.3527G>C p.S1176T | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99929981; called by muse, mutect2, varscan2
- LIG1 | c.858-2A>G p.X286_splice | Splice Site (SNP) | VAF 38/99 reads (38%) | catalogued as COSV99619137; called by muse, mutect2, varscan2
- LIN7A | c.459C>A p.D153E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99692450; called by muse, mutect2, varscan2
- LMX1A | c.348C>A p.H116Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99672811; called by muse, mutect2, varscan2
- LRRC47 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.088); catalogued as COSV100989340; called by muse, mutect2, varscan2
- LRRC49 | c.2048C>G p.T683R | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99537847; called by muse, mutect2, varscan2
- LRRTM3 | c.1067A>T p.K356M | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.593); catalogued as COSV100791764; called by muse, mutect2, varscan2
- LTBP1 | c.4283G>A p.C1428Y (on ENST00000404816 / NM_206943.4; = p.C1102Y on NM_000627.4) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs966309746, COSV99698548; called by muse, mutect2, varscan2
- LVRN | c.2416C>T p.L806F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV100773580; called by muse, mutect2, varscan2
- MAGEC1 | c.1531C>A p.Q511K | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs888074935, COSV99596091; called by muse, mutect2, varscan2
- MAGIX | c.709C>G p.P237A | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.644); catalogued as COSV100891864, COSV100891909; called by muse, mutect2
- MAMSTR | c.876G>C p.E292D (on ENST00000318083 / NM_001130915.2; = p.E189D on NM_182574.2) | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100540564; called by muse, mutect2
- MAP9 | c.1909C>G p.P637A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100251018; called by muse, mutect2, varscan2
- MBD6 | c.2287C>T p.Q763* | Nonsense Mutation (SNP) | VAF 64/155 reads (41%) | catalogued as COSV100851737; called by muse, mutect2, varscan2
- MBOAT1 | c.917T>G p.V306G | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs767362676, COSV100209049; called by muse, mutect2, varscan2
- MINK1 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as rs528570871, COSV99544470; called by muse, mutect2, varscan2
- MPEG1 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs754613970, COSV57090099; called by muse, mutect2, varscan2
- MST1R | c.3316C>G p.Q1106E | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); catalogued as COSV99619232; called by muse, mutect2
- MTFR2 | c.632C>G p.P211R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100886731; called by muse, mutect2, varscan2
- MUC5B | c.14264C>G p.S4755C | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV71592124; called by muse, mutect2, varscan2
- MXRA8 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100492020, COSV100492044; called by muse, mutect2, varscan2
- MYH1 | c.2014C>G p.H672D | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371872450, COSV56857559; called by muse, mutect2, varscan2
- NALCN | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as COSV51919175, COSV99216531; called by muse, mutect2, varscan2
- NCAN | c.3209G>T p.C1070F | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99387842; called by muse, mutect2, varscan2
- NCKAP5 | c.191C>A p.T64K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as COSV100493460; called by muse, mutect2, varscan2
- NCOA6 | c.4456G>C p.E1486Q | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV100750187, COSV62861497; called by muse, mutect2, varscan2
- NF1 | c.6400T>C p.C2134R (on ENST00000358273 / NM_001042492.3; = p.C2113R on NM_000267.3) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1335480997, COSV62199325, COSV62223105; called by muse, mutect2, varscan2
- NFIB | c.1133C>G p.P378R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV101101384; called by muse, mutect2, varscan2
- NIBAN1 | c.720C>G p.I240M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV100836482; called by muse, mutect2, varscan2
- NLGN2 | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV100259534; called by muse, mutect2, varscan2
- NLRP12 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1185856650, COSV60744796; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR1D2 | c.1531C>G p.L511V | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100437541; called by muse, mutect2
- NR2E1 | c.376C>G p.P126A | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV100934591, COSV100934640; called by muse, mutect2, varscan2
- NRCAM | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.031); catalogued as rs757035974, COSV100694550, COSV100695833; called by muse, mutect2, varscan2
- NSD1 | c.4846C>T p.H1616Y | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100729627, COSV100729668; called by muse, mutect2, varscan2
- NSD3 | c.3310G>C p.D1104H | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100395481; called by muse, mutect2
- NUBP2 | c.373dup p.E125Gfs*16 | Frame Shift Ins (INS) | VAF 36/143 reads (25%) | catalogued as rs1237887686; called by mutect2, pindel, varscan2
- NUMA1 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100706398, COSV100706547; called by muse, mutect2, varscan2
- NXPH1 | c.511A>T p.T171S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.264); catalogued as COSV101339752; called by muse, mutect2, varscan2
- OBSCN | c.21031G>C p.G7011R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100804847; called by mutect2, varscan2
- OPCML | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100103378, COSV59430487; called by muse, mutect2, varscan2
- OR10Z1 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs752568772, COSV100779052, COSV63526162; called by muse, mutect2, varscan2
- OR1L3 | c.756T>A p.Y252* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100506284; called by muse, mutect2, varscan2
- OR4C6 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.314); catalogued as COSV58602970; called by muse, mutect2, varscan2
- OR4K17 | c.641T>C p.L214S | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100210749; called by muse, mutect2, varscan2
- OR56B4 | c.681C>G p.I227M | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100337679, COSV57204747; called by muse, mutect2, varscan2
- OR5D13 | c.129del p.N44Tfs*4 | Frame Shift Del (DEL) | VAF 37/127 reads (29%) | catalogued as rs768283553, COSV100686773; called by mutect2, pindel, varscan2
- OR8D2 | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.952); catalogued as COSV100659049; called by muse, mutect2, varscan2
- P4HA2 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as COSV51323972, COSV99387201; called by muse, mutect2, varscan2
- PAPPA2 | c.2961G>T p.L987F | Missense Mutation (SNP) | VAF 94/221 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV100868367; called by muse, mutect2, varscan2
- PAX5 | c.212+2T>C p.X71_splice | Splice Site (SNP) | VAF 50/121 reads (41%) | catalogued as COSV100814434; called by muse, mutect2, varscan2
- PBXIP1 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.372); catalogued as COSV100870108; called by muse, mutect2
- PCDH10 | c.1522C>G p.Q508E | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV99994102; called by muse, mutect2, varscan2
- PCDHA13 | c.361G>C p.V121L | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV99167648; called by muse, mutect2
- PCDHB2 | c.1941G>C p.K647N | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); catalogued as COSV50592098, COSV50619117, COSV99165868; called by muse, mutect2, varscan2
- PCDHGA12 | c.2014C>G p.L672V | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV99341357; called by muse, mutect2, varscan2
- PCDHGA7 | c.82G>C p.A28P | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV99542616; called by muse, mutect2, varscan2
- PCDHGB3 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.546); catalogued as COSV99542614; called by muse, mutect2, varscan2
- PCDHGB4 | c.1442C>G p.P481R | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.392); catalogued as COSV99542618; called by muse, mutect2, varscan2
- PDCD10 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV101208553; called by muse, mutect2, varscan2
- PDHA2 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.184); catalogued as COSV99757111; called by muse, mutect2, varscan2
- PDZD2 | c.2857C>T p.R953* | Nonsense Mutation (SNP) | VAF 11/118 reads (9%) | catalogued as COSV99225919; called by muse, mutect2
- PDZRN4 | c.2695C>G p.R899G (on ENST00000402685 / NM_001164595.2; = p.R641G on NM_013377.4) | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54209543, COSV54218950; called by muse, mutect2, varscan2
- PEDS1 | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100502120; called by muse, mutect2
- PES1 | c.1455G>C p.E485D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV100073243, COSV58829438; called by muse, mutect2
- PHACTR3 | c.707C>G p.T236S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV100732897; called by muse, mutect2, varscan2
- PHKA1 | c.3622G>A p.A1208T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs782814716, COSV100263603; called by muse, mutect2, varscan2
- PIAS3 | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100992747, COSV104427872; called by muse, mutect2, varscan2
- PIK3R5 | c.2321C>A p.T774K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.165); catalogued as COSV99353646; called by muse, mutect2, varscan2
- PKD1 | c.12652G>C p.V4218L (on ENST00000262304 / NM_001009944.3; = p.V4217L on NM_000296.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.114); catalogued as COSV99238605; called by muse, mutect2, varscan2
- PKHD1L1 | c.1265G>C p.G422A | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV101006597; called by muse, mutect2
- PKN1 | c.149T>G p.L50R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99661596; called by muse, mutect2
- PKN2 | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV100281688; called by muse, mutect2
- PLA2G2C | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99930352; called by muse, mutect2, varscan2
- PLEKHH1 | c.847G>C p.G283R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100233343; called by muse, mutect2, varscan2
- PLEKHM3 | c.1808G>T p.R603L | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV101216749, COSV66819038; called by muse, mutect2, varscan2
- PLPPR4 | c.474G>T p.E158D | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100926867; called by muse, mutect2, varscan2
- POLA1 | c.3670T>A p.C1224S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100985661; called by muse, mutect2, varscan2
- POLDIP2 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1295729981, COSV50228437; called by muse, mutect2, varscan2
- POLR2A | c.1213C>G p.L405V | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100496071; called by muse, mutect2
- POLR2M | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV100221290; called by muse, mutect2, varscan2
- POM121L12 | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.964); catalogued as COSV101374951; called by muse, mutect2, varscan2
- POMT1 | c.794G>C p.R265P | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100586520; called by muse, mutect2, varscan2
- POP7 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.381); catalogued as COSV100292184; called by muse, mutect2
- PPP2CB | c.264C>G p.D88E | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99646700; called by muse, mutect2
- PRAG1 | c.1708C>G p.L570V | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.46); catalogued as COSV100422505; called by muse, mutect2, varscan2
- PRKD1 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.726); catalogued as rs1291517960, COSV100121118; called by muse, mutect2, varscan2
- PSMD2 | c.1803A>C p.A601= | Splice Region (SNP) | VAF 28/78 reads (36%) | catalogued as COSV100031905; called by muse, mutect2, varscan2
- PTPRD | c.1736G>A p.S579N | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV61955080, COSV61970895; called by muse, mutect2, varscan2
- PTPRD | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100645795; called by muse, mutect2, varscan2
- PTPRG | c.1075A>G p.N359D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99876076; called by muse, mutect2, varscan2
- PTPRZ1 | c.2251C>G p.P751A | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as rs1232557659, COSV101100521; called by muse, mutect2
- PXDNL | c.2879G>C p.R960P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100685055, COSV62479321; called by muse, varscan2
- PYGM | c.538G>C p.A180P | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV99377366; called by muse, mutect2
- PYM1 | c.526G>C p.V176L | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100212673; called by muse, mutect2
- R3HDM1 | c.2546C>A p.P849Q | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV99926498; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1127T>G p.V376G | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100365580; called by muse, mutect2, varscan2
- RANBP6 | c.1900G>C p.V634L | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99424289; called by muse, mutect2, varscan2
- RARB | c.902G>T p.G301V (on ENST00000383772 / NM_001290216.2; = p.G294V on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99980030; called by muse, mutect2, varscan2
- RBM15B | c.1525C>G p.H509D | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.724); catalogued as COSV100082242; called by muse, mutect2, varscan2
- RBMXL2 | c.666C>A p.S222R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); catalogued as COSV100182373, COSV60978868; called by muse, mutect2, varscan2
- RC3H2 | c.1711G>C p.E571Q | Missense Mutation (SNP) | VAF 17/336 reads (5%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.932); catalogued as COSV100605841; called by muse, mutect2
- RETREG3 | c.731G>C p.R244P | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.465); catalogued as COSV100515110, COSV58703734; called by muse, mutect2
- RHOA | c.492A>T p.K164N | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as COSV101346310; called by muse, mutect2, varscan2
- RNASE3 | c.383G>C p.R128T | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100484191, COSV58959180; called by muse, mutect2
- RNF19A | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV100347939; called by muse, mutect2, varscan2
- RP1L1 | c.5976G>C p.E1992D | Missense Mutation (SNP) | VAF 32/632 reads (5%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.258); catalogued as COSV101223443; called by muse, mutect2
- RPH3AL | c.579G>C p.E193D | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.225); catalogued as COSV100047527; called by muse, mutect2, varscan2
- RRAGC | c.264C>G p.N88K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV100883843; called by muse, mutect2, varscan2
- RSPO2 | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV99410034; called by muse, mutect2, varscan2
- RSRC1 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV99906632; called by muse, varscan2
- RTF1 | c.632G>C p.R211P | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV101048025; called by mutect2, varscan2
- RUNX1T1 | c.821A>T p.Q274L (on ENST00000265814 / NM_001198628.1; = p.Q247L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV99753486; called by muse, mutect2, varscan2
- RYR3 | c.6144G>A p.M2048I | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV101213264; called by muse, mutect2, varscan2
- SCAF11 | c.3421G>T p.G1141* | Nonsense Mutation (SNP) | VAF 35/145 reads (24%) | catalogued as COSV101014517; called by muse, mutect2, varscan2
- SCN1A | c.5029C>A p.L1677I (on ENST00000303395 / NM_001202435.3; = p.L1666I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM096166, COSV100321236; called by muse, mutect2, varscan2
- SCN5A | c.1903G>C p.E635Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.307); catalogued as COSV61143847; called by muse, mutect2, varscan2
- SCN5A | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100349542; called by muse, mutect2, varscan2
- SCN7A | c.1832C>A p.P611Q | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs377740490, COSV101313307; called by muse, mutect2, varscan2
- SELPLG | c.48C>G p.N16K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99947554; called by muse, mutect2, varscan2
- SEMA3E | c.1708C>A p.Q570K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.416); catalogued as COSV57084549, COSV57115083; called by muse, mutect2, varscan2
- SEMA4D | c.2466C>G p.I822M | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV100358604, COSV59400019; called by muse, mutect2, varscan2
- SFTPC | c.233C>G p.A78G | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.381); catalogued as COSV100109891; called by muse, mutect2
- SIGLEC9 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as COSV99142885; called by muse, mutect2, varscan2
- SLC16A13 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.125); catalogued as COSV100340150, COSV57287513; called by muse, mutect2, varscan2
- SLC25A14 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99502534; called by muse, mutect2, varscan2
- SLC2A12 | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445631403, COSV99260268; called by muse, mutect2, varscan2
- SLC35G3 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs143192040; called by muse, mutect2, varscan2
- SLITRK2 | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV100157994; called by muse, mutect2, varscan2
- SLITRK2 | c.2166C>A p.N722K | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs940264529, COSV100157999; called by muse, mutect2, varscan2
- SLITRK5 | c.239G>C p.R80P | Missense Mutation (SNP) | VAF 79/232 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100280998; called by muse, mutect2, varscan2
- SLTM | c.2155G>C p.E719Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99989309; called by muse, mutect2, varscan2
- SMS | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV101048190; called by muse, mutect2, varscan2
- SNX12 | c.382A>G p.N128D | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.763); catalogued as COSV99339932; called by muse, mutect2, varscan2
- SOBP | c.1228C>G p.P410A | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58003312; called by muse, mutect2, varscan2
- SON | c.5502C>G p.H1834Q | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as COSV99279218; called by muse, mutect2
- SORL1 | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99494723; called by muse, mutect2
- SOX1 | c.317G>T p.R106L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1315477523, COSV100446999; called by muse, mutect2, varscan2
- SPG21 | c.528G>A p.M176I | Missense Mutation (SNP) | VAF 122/371 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99200199; called by muse, varscan2
- SPNS3 | c.222G>C p.E74D | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100337090; called by muse, mutect2, varscan2
- SRCAP | c.7676C>G p.A2559G | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.172); catalogued as COSV99350748; called by muse, mutect2
- SSH2 | c.108C>G p.S36R | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV99282575; called by muse, mutect2
- STEAP3 | c.1021G>C p.V341L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV100713421; called by muse, mutect2, varscan2
- STRADA | c.558C>G p.I186M (on ENST00000336174 / NM_001363786.1; = p.I149M on NM_153335.6) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99835261; called by muse, varscan2
- STS | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99481485; called by muse, mutect2, varscan2
- STX4 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100572962, COSV58268590; called by muse, mutect2, varscan2
- SYNE1 | c.17872C>T p.L5958F (on ENST00000367255 / NM_182961.4; = p.L5887F on NM_033071.3) | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99572725; called by muse, mutect2, varscan2
- SYNE1 | c.14228C>A p.T4743K (on ENST00000367255 / NM_182961.4; = p.T4672K on NM_033071.3) | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99557638, COSV99572729; called by muse, mutect2, varscan2
- SYNE2 | c.8051G>A p.G2684E | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.08); catalogued as rs374785983; called by muse, mutect2, varscan2
- TAB3 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99916499; called by muse, mutect2, varscan2
- TBC1D13 | c.619C>G p.H207D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99804578; called by muse, mutect2, varscan2
- TCF20 | c.5054C>T p.S1685L | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs267606263, COSV59488860; called by muse, mutect2, varscan2
- TCN1 | c.464G>T p.C155F | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99953362; called by muse, mutect2, varscan2
- TCN2 | c.111C>G p.H37Q | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99308681; called by muse, mutect2, varscan2
- TENM1 | c.1799C>T p.T600I | Missense Mutation (SNP) | VAF 115/308 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as COSV100950460; called by muse, mutect2, varscan2
- TENT5D | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100382851; called by muse, mutect2, varscan2
- THAP12 | c.1923G>T p.E641D | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV99473136; called by muse, mutect2, varscan2
- THSD7A | c.4334C>T p.S1445F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101448810; called by muse, mutect2, varscan2
- TINAG | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs750703188, COSV52506013; called by muse, mutect2, varscan2
- TLR7 | c.1307C>G p.S436* | Nonsense Mutation (SNP) | VAF 51/122 reads (42%) | catalogued as COSV101028007; called by muse, mutect2, varscan2
- TMCO5A | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs768532037, COSV100148634; called by muse, mutect2, varscan2
- TMEM126A | c.393C>G p.A131= | Splice Region (SNP) | VAF 15/74 reads (20%) | catalogued as COSV99476394; called by muse, mutect2, varscan2
- TMEM132D | c.1413G>C p.E471D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as COSV101398830; called by muse, mutect2
- TMEM177 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99733681; called by muse, mutect2, varscan2
- TMPRSS11D | c.279A>C p.L93F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99384865; called by muse, mutect2, varscan2
- TMPRSS2 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs574582815, COSV100151993; called by muse, mutect2, varscan2
- TNC | c.3577G>C p.E1193Q | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV100406062; called by muse, mutect2, varscan2
- TNFRSF8 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV99821744; called by muse, mutect2, varscan2
- TRAP1 | c.576G>T p.E192D | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs763585509, COSV99893730; called by muse, mutect2, varscan2
- TRIM10 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.239); catalogued as rs779269542, COSV100938883; called by muse, mutect2, varscan2
- TRIM28 | c.2431G>C p.E811Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1358145803; called by muse, mutect2
- TTC16 | c.2207C>G p.T736S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as COSV100263125; called by muse, mutect2, varscan2
- TTC17 | c.2771C>G p.S924C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV99235658; called by muse, mutect2, varscan2
- TTN | c.67993A>G p.S22665G (on ENST00000591111; = p.S15241G on NM_003319.4) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | PolyPhen benign (0.024); catalogued as COSV100621699; called by muse, mutect2, varscan2
- TTN | c.64676A>G p.K21559R (on ENST00000591111; = p.K14135R on NM_003319.4) | Missense Mutation (SNP) | VAF 98/282 reads (35%) | PolyPhen benign (0.043); catalogued as COSV100621701; called by muse, mutect2
- TTN | c.64674C>A p.C21558* (on ENST00000591111; = p.C14134* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 100/288 reads (35%) | catalogued as rs1415191718, COSV60206191; called by muse, mutect2
- U2AF2 | c.912C>G p.F304L | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as COSV100454370; called by muse, mutect2
- UGT2B4 | c.1252C>A p.H418N | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59319636; called by muse, mutect2, varscan2
- USP13 | c.169-1G>C p.X57_splice | Splice Site (SNP) | VAF 13/183 reads (7%) | catalogued as COSV99831475; called by muse, mutect2
- USP32 | c.4429G>C p.E1477Q | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.147); catalogued as COSV100342458; called by muse, mutect2
- USP45 | c.1185G>C p.W395C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.319); catalogued as COSV100569834; called by muse, mutect2, varscan2
- VCAN | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1343788478, COSV99426651; called by muse, mutect2, varscan2
- VIPR1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100285700; called by muse, mutect2, varscan2
- VIRMA | c.3034C>G p.L1012V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV52589489, COSV99888926; called by muse, mutect2
- VN1R2 | c.390C>A p.H130Q | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV100448075; called by muse, mutect2, varscan2
- VSIG10 | c.745G>T p.G249W | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100821328; called by muse, mutect2
- VSIG10 | c.743A>T p.D248V | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.193); catalogued as COSV100821329; called by muse, mutect2
- VWA3B | c.3445A>T p.I1149F | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1453129814, COSV101417834; called by muse, mutect2, varscan2
- WDR25 | c.291G>C p.Q97H | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV100092059; called by muse, mutect2, varscan2
- WDR45 | c.165G>T p.E55D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV100540334; called by muse, mutect2, varscan2
- WDR49 | c.499G>C p.D167H (on ENST00000308378 / NM_001366158.1; = p.D508H on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as COSV100393378; called by muse, mutect2, varscan2
- WFDC2 | c.231G>C p.E77D | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.348); catalogued as COSV99463761; called by muse, mutect2, varscan2
- WWC3 | c.3253C>G p.P1085A | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV101081621; called by muse, mutect2
- XIRP2 | c.3838C>G p.L1280V (on ENST00000628543; = p.L1455V on NM_152381.6) | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54715295, COSV99745408; called by muse, mutect2, varscan2
- XYLT1 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.003); catalogued as COSV99762626; called by muse, mutect2, varscan2
- YTHDF1 | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); catalogued as COSV100945597; called by muse, mutect2, varscan2
- ZBED1 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV58131085; called by muse, mutect2, varscan2
- ZC3H14 | c.1658C>G p.S553* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as COSV99193156, COSV99193286; called by muse, mutect2, varscan2
- ZDHHC6 | c.550G>C p.D184H | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as rs778187892, COSV101024430; called by muse, mutect2, varscan2
- ZFP57 | c.1372C>T p.H458Y | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM083211, COSV100971923; called by muse, mutect2, varscan2
- ZHX2 | c.304C>G p.P102A | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100073519; called by muse, mutect2
- ZKSCAN5 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.193); catalogued as COSV100460303; called by muse, mutect2
- ZNF208 | c.470G>A p.C157Y | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.264); catalogued as COSV101237154, COSV68101374; called by muse, mutect2, varscan2
- ZNF227 | c.1200G>C p.R400S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV100480514, COSV57313975; called by muse, mutect2, varscan2
- ZNF232 | c.502C>G p.P168A | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV100005746; called by muse, mutect2, varscan2
- ZNF236 | c.3704A>T p.K1235M | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99470803; called by muse, mutect2, varscan2
- ZNF331 | c.539T>A p.I180N | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV53477491; called by muse, mutect2, varscan2
- ZNF572 | c.914G>C p.C305S | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100074045; called by muse, mutect2
- ZNF711 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV52154401, COSV99341379; called by muse, mutect2, varscan2
- ZP1 | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV99612660; called by muse, mutect2, varscan2
- ZPBP | c.225G>C p.M75I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV99250120; called by muse, mutect2, varscan2
- ZPLD1 | c.66C>A p.N22K (on ENST00000466937 / NM_001329788.1; = p.N38K on NM_175056.2) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.32); catalogued as COSV100083416, COSV60355735; called by muse, mutect2, varscan2
- ZSCAN21 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as rs1303232731, COSV52849187; called by muse, mutect2, varscan2
- ZXDA | c.1720C>A p.L574I | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs761202686, COSV62387960; called by muse, mutect2, varscan2
- AATF | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ACP6 | c.353del p.G118Afs*7 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- CBWD6 | c.431G>C p.G144A | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CLUH | c.3425_3433del p.A1142_K1144del (on ENST00000435359; = p.A1181_K1183del on NM_015229.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- CYP1A1 | c.1340_1352del p.V447Afs*36 | Frame Shift Del (DEL) | VAF 30/139 reads (22%) | called by mutect2, pindel, varscan2
- DCAF12L2 | c.1109G>C p.G370A | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2
- FOXD4L6 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by mutect2, varscan2
- FRY | c.7818dup p.E2607* | Frame Shift Ins (INS) | VAF 20/65 reads (31%) | called by mutect2, pindel, varscan2
- IGHV4-61 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- KRTAP6-1 | c.114_115del p.C38Wfs*59 | Frame Shift Del (DEL) | VAF 60/202 reads (30%) | called by pindel, varscan2
- MCM3 | c.1131del p.T378Pfs*11 (on ENST00000229854 / NM_001366374.2; = p.T368Pfs*11 on NM_002388.6 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- MET | c.3522+1G>C p.X1174_splice | Splice Site (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- MPC1 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRPL2 | c.648_653dup p.L217_R218dup | In Frame Ins (INS) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- NSD1 | c.5858del p.G1953Vfs*16 | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | called by mutect2, pindel, varscan2
- PAGR1 | c.510del p.F170Lfs*6 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- PBX1 | c.755del p.F252Sfs*18 | Frame Shift Del (DEL) | VAF 31/189 reads (16%) | called by mutect2, pindel, varscan2
- RRN3 | c.1445G>T p.G482V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMA6D | c.2679del p.A895Pfs*13 (on ENST00000316364 / NM_153618.2; = p.A833Pfs*13 on NM_020858.2) | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | called by mutect2, varscan2
- SLC26A5 | c.1678-1G>A p.X560_splice | Splice Site (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2
- TAFA5 | c.316del p.E106Kfs*6 (on ENST00000402357 / NM_001082967.3; = p.E99Kfs*6 on NM_015381.7) | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | called by mutect2, pindel, varscan2
- TTN | c.40407dup p.G13470Wfs*7 (on ENST00000591111; = p.G6046Wfs*7 on NM_003319.4) | Frame Shift Ins (INS) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- TTN | c.26040del p.C8681Vfs*2 (on ENST00000591111; = p.C7754Vfs*2 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- ZNF239 | c.867dup p.P290Tfs*3 | Frame Shift Ins (INS) | VAF 42/171 reads (25%) | called by pindel, varscan2
- ZNF239 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- ACAN | c.2934T>A p.S978= | Silent (SNP) | VAF 94/290 reads (32%) | catalogued as COSV100718754; called by muse, varscan2
- ADAM32 | c.1536T>C p.N512= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as COSV101165442; called by muse, mutect2, varscan2
- ADAMTS14 | c.2556G>C p.A852= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100941735, COSV64604937; called by muse, mutect2, varscan2
- ADGRL4 | c.1860C>T p.A620= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV100876280; called by muse, mutect2, varscan2
- AGAP1 | c.621C>T p.Y207= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as COSV100366275; called by muse, mutect2, varscan2
- AIFM1 | c.912G>C p.T304= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV99780698, COSV99781254; called by muse, mutect2, varscan2
- AP3D1 | c.3021C>G p.T1007= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV100642840; called by muse, mutect2
- ARHGAP36 | c.615C>A p.T205= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99357970; called by muse, mutect2, varscan2
- C5orf51 | c.801G>A p.V267= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs753355135, COSV101069018; called by muse, mutect2, varscan2
- CA2 | c.702T>C p.G234= | Silent (SNP) | VAF 52/93 reads (56%) | catalogued as COSV99570181; called by muse, mutect2, varscan2
- CBLL2 | c.282G>C p.P94= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV100081673, COSV60369185; called by muse, mutect2, varscan2
- CCL18 | c.234C>A p.V78= | Silent (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- CDCP2 | c.672C>G p.P224= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100313590; called by muse, mutect2
- CLIC2 | c.255A>G p.K85= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV100425679; called by muse, mutect2, varscan2
- CLRN2 | c.324C>G p.A108= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as COSV101566455; called by muse, mutect2
- CRB1 | c.1593G>C p.V531= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV100957999; called by muse, mutect2, varscan2
- CXorf66 | c.219C>T p.S73= | Silent (SNP) | VAF 150/376 reads (40%) | catalogued as rs755958848, COSV100983914; called by muse, varscan2
- DCN | c.294T>C p.D98= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99272464; called by muse, mutect2, varscan2
- DEPDC7 | c.885A>G p.T295= (on ENST00000241051 / NM_001077242.2; = p.T286= on NM_139160.2) | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV99572820; called by muse, mutect2, varscan2
- DGKK | c.111G>A p.P37= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs782008790, COSV101053122; called by muse, mutect2, varscan2
- DLC1 | c.2862G>T p.V954= (on ENST00000276297 / NM_001348081.2; = p.V517= on NM_006094.5) | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV99364397; called by muse, mutect2, varscan2
- EEF2K | c.843C>G p.L281= | Silent (SNP) | VAF 11/150 reads (7%) | catalogued as COSV99533416; called by muse, mutect2
- ERICH3 | c.2574C>A p.P858= | Silent (SNP) | VAF 66/162 reads (41%) | catalogued as COSV100445062; called by muse, mutect2, varscan2
- FKBP15 | c.2695C>A p.R899= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as COSV99439342; called by muse, mutect2, varscan2
- FMN2 | c.1336C>A p.R446= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV100146413, COSV60427335; called by muse, mutect2, varscan2
- GABRG1 | c.195A>T p.T65= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as COSV99778461; called by muse, mutect2, varscan2
- GABRG2 | c.543C>A p.T181= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV100729776; called by muse, mutect2, varscan2
- GFPT2 | c.267C>G p.A89= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV99517907; called by muse, mutect2, varscan2
- GFRA2 | c.351C>G p.T117= | Silent (SNP) | VAF 9/15 reads (60%) | called by muse, varscan2
- GRIA3 | c.1419C>A p.S473= | Silent (SNP) | VAF 64/179 reads (36%) | catalogued as COSV99991007; called by muse, mutect2, varscan2
- GRM8 | c.360G>T p.V120= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV58816787; called by muse, mutect2, varscan2
- GTF3C5 | c.495G>A p.P165= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as rs138342612; called by muse, mutect2, varscan2
- HECW2 | c.2331T>C p.A777= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as rs1228572141, COSV99648051; called by muse, mutect2, varscan2
- HLA-DQB1 | c.645C>A p.P215= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV100891313; called by muse, mutect2
- HTT | c.1512A>T p.T504= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100751038; called by muse, mutect2, varscan2
- IFT27 | c.366G>C p.G122= (on ENST00000433985 / NM_001363003.2; = p.G121= on NM_006860.5) | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100503592; called by muse, mutect2, varscan2
- IL1RAPL1 | c.939G>A p.Q313= | Silent (SNP) | VAF 50/134 reads (37%) | catalogued as COSV100148695; called by muse, mutect2, varscan2
- ILF2 | c.321C>G p.S107= | Silent (SNP) | VAF 32/267 reads (12%) | catalogued as COSV100721975, COSV62627834; called by muse, mutect2, varscan2
- KCNH8 | c.1248G>A p.S416= | Silent (SNP) | VAF 28/202 reads (14%) | catalogued as rs758740707, COSV60478451; called by muse, varscan2
- KCNK13 | c.891G>C p.G297= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV56414726; called by muse, mutect2, varscan2
- KIAA1549L | c.3447G>A p.L1149= (on ENST00000321505; = p.L1446= on NM_012194.3) | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV99683974; called by muse, mutect2, varscan2
- KLHL13 | c.1716C>A p.A572= | Silent (SNP) | VAF 36/207 reads (17%) | catalogued as COSV99452156; called by muse, mutect2, varscan2
- LAMA4 | c.2145C>T p.A715= (on ENST00000230538 / NM_001105206.3; = p.A708= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs70940810, COSV100038916; called by muse, mutect2, varscan2
- MAP2K6 | c.228G>C p.G76= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100765108; called by muse, mutect2, varscan2
- MORC2 | c.1065C>G p.A355= (on ENST00000397641 / NM_001303256.3; = p.A293= on NM_014941.3) | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99310167; called by muse, mutect2
- MPEG1 | c.921C>G p.G307= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99915713; called by muse, mutect2
- MPIG6B | c.288C>G p.L96= | Silent (SNP) | VAF 10/167 reads (6%) | catalogued as COSV101008137; called by muse, mutect2
- MYH6 | c.3492G>A p.E1164= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100676810; called by muse, mutect2, varscan2
- NELL1 | c.1986C>T p.G662= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100123062; called by muse, mutect2, varscan2
- NKAP | c.132G>T p.S44= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV101004266; called by muse, mutect2, varscan2
- NPAP1 | c.540T>A p.L180= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100275736; called by muse, mutect2, varscan2
- NRROS | c.1554C>T p.L518= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as COSV100145556; called by muse, mutect2, varscan2
- OMD | c.687T>C p.P229= | Silent (SNP) | VAF 57/131 reads (44%) | catalogued as COSV100979070; called by muse, mutect2, varscan2
- OR2T11 | c.465G>A p.L155= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV100424895; called by muse, mutect2, varscan2
- OR4C6 | c.690G>A p.G230= | Silent (SNP) | VAF 52/121 reads (43%) | catalogued as rs368640550; called by muse, mutect2, varscan2
- OR51T1 | c.108C>G p.L36= | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as COSV100434445; called by muse, mutect2
- OR52I2 | c.672C>G p.P224= | Silent (SNP) | VAF 48/204 reads (24%) | catalogued as COSV100442973; called by muse, mutect2, varscan2
- PACRG | c.435C>A p.V145= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1318499108, COSV100434551; called by muse, mutect2, varscan2
- PCDHB9 | c.1656G>T p.L552= | Silent (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- PCNT | c.5343G>T p.G1781= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV100855783; called by muse, mutect2, varscan2
- PPP1R15A | c.1926C>T p.S642= | Silent (SNP) | VAF 81/239 reads (34%) | catalogued as COSV99566167; called by muse, mutect2, varscan2
- PSG6 | c.573G>A p.R191= | Silent (SNP) | VAF 81/185 reads (44%) | catalogued as rs1058688, COSV51831805, COSV99414322; called by muse, mutect2, varscan2
- PTPRJ | c.2739C>G p.T913= | Silent (SNP) | VAF 31/143 reads (22%) | catalogued as COSV101395529; called by muse, mutect2, varscan2
- PXDN | c.3153C>T p.H1051= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs551163043, COSV53234104; called by mutect2, varscan2
- QPCTL | c.367C>T p.L123= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV99171300; called by muse, mutect2, varscan2
- RABEP1 | c.1903C>A p.R635= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV99336849; called by muse, mutect2, varscan2
- RALGAPB | c.3201C>G p.A1067= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99485512; called by muse, mutect2, varscan2
- RELCH | c.162G>A p.S54= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV56888241, COSV99902520; called by muse, mutect2
- REST | c.2412C>G p.P804= | Silent (SNP) | VAF 45/228 reads (20%) | catalogued as COSV100471185; called by muse, mutect2, varscan2
- RGL2 | c.1584G>A p.L528= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV101004816; called by muse, mutect2, varscan2
- RHOBTB3 | c.273G>C p.G91= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV101183232; called by muse, mutect2, varscan2
- RNF113B | c.207C>A p.L69= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99940386; called by muse, mutect2, varscan2
- RPAIN | c.405C>T p.L135= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100506879; called by muse, mutect2, varscan2
- S100A7A | c.294G>A p.G98= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100241625; called by muse, mutect2, varscan2
- SEC22A | c.630C>T p.G210= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as COSV100007077; called by muse, mutect2, varscan2
- SERPINA10 | c.273C>G p.S91= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100003931; called by muse, mutect2, varscan2
- SH2D4A | c.306C>G p.A102= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV99744956; called by muse, mutect2
- SH3TC1 | c.681C>T p.P227= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV99795144; called by muse, mutect2, varscan2
- SLC35G2 | c.444G>C p.V148= | Silent (SNP) | VAF 24/187 reads (13%) | catalogued as COSV101262073; called by muse, mutect2, varscan2
- SLC6A11 | c.363T>C p.C121= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs1433740693, COSV99594788; called by muse, mutect2, varscan2
- SMURF2 | c.1542G>C p.G514= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99300903; called by muse, mutect2, varscan2
- SNRNP200 | c.4047G>A p.G1349= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as COSV100107863; called by muse, mutect2, varscan2
- SNTA1 | c.522G>C p.P174= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV99458837; called by muse, mutect2
- STIMATE-MUSTN1 | c.1068G>A p.E356= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV99819657; called by muse, mutect2, varscan2
- SYNE2 | c.516C>T p.C172= | Silent (SNP) | VAF 61/184 reads (33%) | catalogued as rs781106587, COSV100420297; called by muse, mutect2, varscan2
- SYT3 | c.342G>C p.G114= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV100144215; called by muse, mutect2, varscan2
- TAGLN2 | c.429C>G p.L143= | Silent (SNP) | VAF 11/127 reads (9%) | catalogued as COSV100231238; called by muse, mutect2
- TASOR2 | c.5760G>C p.G1920= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV60167279; called by muse, mutect2, varscan2
- TBC1D10A | c.537A>G p.L179= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV99304775; called by muse, mutect2, varscan2
- TMEM35A | c.78C>A p.I26= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV100877489, COSV65863651; called by muse, mutect2, varscan2
- TNIP2 | c.996C>T p.A332= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as rs761938486, COSV100198715; called by muse, mutect2, varscan2
- TNXB | c.3480G>T p.A1160= | Silent (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- TOMM40L | c.543G>A p.E181= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV63467907; called by muse, mutect2, varscan2
- TTN | c.71964G>A p.G23988= (on ENST00000591111; = p.G16564= on NM_003319.4) | Silent (SNP) | VAF 92/240 reads (38%) | catalogued as COSV100621692; called by muse, mutect2, varscan2
- TTN | c.17607G>T p.T5869= (on ENST00000591111; = p.T4942= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/166 reads (37%) | catalogued as COSV100621706, COSV59865395; called by muse, mutect2, varscan2
- UBC | c.2049G>C p.G683= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV100299058; called by muse, mutect2, varscan2
- UNC5C | c.1098T>C p.L366= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs1298018766, COSV101497967; called by muse, mutect2, varscan2
- UNC5D | c.1533C>T p.P511= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs1227092630; called by muse, mutect2, varscan2
- WDR73 | c.832C>T p.L278= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100822101; called by muse, mutect2, varscan2
- XK | c.39G>C p.L13= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV101064747; called by muse, mutect2, varscan2
- YME1L1 | c.1872G>T p.R624= (on ENST00000326799 / NM_139312.3; = p.R567= on NM_014263.4) | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100463942; called by muse, mutect2, varscan2
- ZFAND1 | c.573G>A p.K191= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as rs1195970027, COSV99605476; called by muse, mutect2, varscan2
- ZNF366 | c.2133C>T p.G711= | Silent (SNP) | VAF 41/123 reads (33%) | catalogued as COSV100574348; called by muse, mutect2, varscan2
- ZNF486 | c.450G>A p.Q150= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV100631344, COSV100631512; called by muse, mutect2, varscan2
- ZNF714 | c.276G>C p.V92= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99395426; called by muse, mutect2, varscan2
- ZNF804B | c.271C>A p.R91= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100304900, COSV60821417, COSV60829860; called by muse, mutect2, varscan2
- AC245047.1 | n.157A>G | RNA (SNP) | VAF 76/202 reads (38%) | called by muse, mutect2, varscan2
- BCOR | c.-1C>A | 5'UTR (SNP) | VAF 31/73 reads (42%) | catalogued as COSV100653620; called by muse, mutect2, varscan2
- CFAP47 | c.5536-633A>G | Intron (SNP) | VAF 29/73 reads (40%) | catalogued as COSV100545574; called by muse, mutect2, varscan2
- CYHR1 | c.246+96G>C | Intron (SNP) | VAF 129/231 reads (56%) | catalogued as COSV100023906; called by muse, mutect2, varscan2
- DMD | c.31+83125G>A | Intron (SNP) | VAF 6/15 reads (40%) | catalogued as COSV55855560, COSV99924340; called by muse, mutect2, varscan2
- DNAJB11 | c.*2A>G | 3'UTR (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99408680; called by muse, mutect2, varscan2
- GOSR2 | chr17:46940579 C>G | 3'Flank (SNP) | VAF 10/143 reads (7%) | catalogued as COSV99846203; called by muse, mutect2
- SLC39A14 | c.457+1519C>G | Intron (SNP) | VAF 18/256 reads (7%) | catalogued as COSV99249897; called by muse, mutect2
- STMP1 | chr7:135660594 G>T | 5'Flank (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- TRAV36DV7 | chr14:22222222 C>T | 5'Flank (SNP) | VAF 18/61 reads (30%) | catalogued as rs1332218369; called by muse, mutect2, varscan2
- VPS11 | chr11:119069201 G>C | 5'Flank (SNP) | VAF 14/178 reads (8%) | catalogued as COSV100333886; called by muse, mutect2
- XIST | n.11216T>A | RNA (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
